Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A7NU, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A7NU-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODE, LEVEL 10, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 2: LYMPH NODE, LEVEL 9, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 3: LYMPH NODE, LEVEL 7, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 4: LYMPH NODE, LEVEL 7 BETA, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: LYMPH NODE, LEVEL 7 GAMMA, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 6: ESOPHAGUS AND STOMACH, MINIMALLY INVASIVE ESOPHAGOGASTRECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING GE JUNCTION, 3.5 CM.
B. CARCINOMA INVADES THROUGH MUSCULARIS PROPRIA INTO ADENTITIA.
C. EXTENSIVE LYMPHVASCULAR SPACE AND PERINEURAL INVASION.
D. METASTATIC CARCINOMA TO TWELVE OF TWELVE LYMPH NODES (12/12).
E. FOCI OF BARRETT'S ESOPHAGUS WITH HIGH GRADE DYSPLASIA.
F. MARGINS NEGATIVE FOR CARCINOMA.
G. AJCC 7TH EDITION PATHOLOGIC TUMOR STAGE IS: pT3 N3.

PART 7: LYMPH NODE, FAT PAD, BIOPSY -
METASTATIC CARCINOMA TO ONE LYMPH NODE (1/1).

PART 8: LYMPH NODE, GASTRIC FAT, BIOPSY -
METASTATIC CARCINOMA TO ONE LYMPH NODE (1/1).

PART 9: LYMPH NODE, PERIGASTRIC, BIOPSY -
FAT NECROSIS, NEGATIVE FOR MALIGNANCY.

PART 10: ESOPHAGUS AND STOMACH, ANASTOMOSIS, MINIMALLY INVASIVE ESOPHAGOGASTRECTOMY -
MARGINS NEGATIVE FOR CARCINOMA.

PART 11: PROXIMAL STOMACH, MINIMALLY INVASIVE ESOPHAGOGASTRECTOMY -
NEGATIVE FOR CARCINOMA.

ICD-O-3
Adenocarcinoma NOS
8140/3
Site GE junction C16.0
JWS 9/24/13

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Esophagogastrectomy
TUMOR SITE: Tumor midpoint centered on esophagogastric junction
TUMOR SIZE: Greatest dimension: 3.5 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: G3
PATHOLOGIC STAGING (pTNM)
pT3
pN3
Number of lymph nodes examined: 12
Number of lymph nodes involved: 12
17 or more regional lymph nodes were identified
pM Not applicable
PRIOR TREATMENT: Treatment history not known
MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma
Distance of invasive carcinoma from closest margin: 1 mm
Specify margin: ADVENTITIAL

ANGIOLYMPHATIC INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: High grade dysplasia

Source: NCI Genomic Data Commons file b5d5b1fc-75eb-48c5-8010-13436f79a86e (TCGA-IN-A7NU.B3C47BB0-94E7-4649-AFD1-0BA5045D28D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).